Somatic mutation profile of tumor specimen 0DR9C4 from CCDI case PBCFZF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Pineal gland; Age at diagnosis: 12.7 years (4,654 days).
Specimen 0DR9C4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67d5a3f8-1b5a-429e-a0e1-fb5ca6622f8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR9CR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b550f28e-3899-49b6-8581-cf8bff5d26ca

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 5'UTR 2, Splice Site 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAIAP3 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 82/826 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs970972501, COSV60979413; called by muse, varscan2
- OR5L1 | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 946/2104 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.836); catalogued as COSV61734719; called by muse, varscan2
- ADGRG3 | c.1253A>G p.E418G | Missense Mutation (SNP) | VAF 128/838 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); called by muse, varscan2
- CACNA1B | c.4843A>G p.I1615V | Missense Mutation (SNP) | VAF 723/1742 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); called by muse, varscan2
- RENBP | c.980G>A p.S327N | Missense Mutation (SNP) | VAF 329/1435 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, varscan2
- TTC31 | c.928+2T>C p.X310_splice | Splice Site (SNP) | VAF 385/847 reads (45%) | called by muse, varscan2
- ZNF135 | c.43dup p.T15Nfs*3 | Frame Shift Ins (INS) | VAF 478/1178 reads (41%) | called by pindel, varscan2
- MYO15A | c.7290T>C p.T2430= | Silent (SNP) | VAF 357/848 reads (42%) | called by muse, varscan2
- KMT2E | c.-57T>C | 5'UTR (SNP) | VAF 106/218 reads (49%) | called by muse, varscan2
- TRMT44 | c.-24A>G | 5'UTR (SNP) | VAF 28/292 reads (10%) | called by muse, varscan2
